FM case AD16186 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/83c1551d-6146-4170-8f6d-b34f2ac2c3f4

Female, 68.7 years: diagnosis not reported by GDC; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
